Somatic mutation profile of tumor specimen TCGA-DX-A1KX-01A (aliquot TCGA-DX-A1KX-01A-22D-A24N-09) from TCGA case TCGA-DX-A1KX, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 67.9 years (24,784 days).
Specimen TCGA-DX-A1KX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2b958ec-6e8e-4122-945a-31a839503068.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A1KX-10A (Blood Derived Normal), aliquot TCGA-DX-A1KX-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b538f25b-59cd-46a0-ae2d-9dc9426077b3

The open-access MAF lists 92 somatic variants for this specimen: 67 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 22, Nonsense Mutation 8, RNA 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD15 | c.1208G>A p.W403* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100212973; called by muse, mutect2, varscan2
- ACSM5 | c.1298A>G p.N433S | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs984503539, COSV100088927; called by muse, mutect2, varscan2
- ADGRV1 | c.13207G>C p.D4403H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67984928; called by muse, mutect2, varscan2
- AFF2 | c.3184A>G p.K1062E | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99664047, COSV99665787; called by muse, mutect2, varscan2
- ALDH1A2 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.797); catalogued as COSV99990720; called by muse, mutect2, varscan2
- AMBRA1 | c.3721C>T p.R1241W (on ENST00000458649 / NM_001367468.1; = p.R1151W on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs772046544, COSV54049799; called by muse, mutect2, varscan2
- AP4B1 | c.1821G>T p.E607D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.033); catalogued as COSV99870803; called by muse, mutect2, varscan2
- ARHGAP22 | c.1896A>T p.R632S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV99985258; called by muse, mutect2, varscan2
- ASB2 | c.1510T>A p.W504R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100279346; called by muse, mutect2, varscan2
- CALHM2 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV99588614; called by muse, mutect2
- CBR3 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99289813; called by muse, mutect2, varscan2
- CHP2 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100270168; called by muse, mutect2, varscan2
- CLVS2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs776841053, COSV51559845; called by muse, mutect2, varscan2
- CTPS1 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 25/145 reads (17%) | catalogued as COSV65452748; called by muse, mutect2, varscan2
- DDX60 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV101190473; called by muse, mutect2, varscan2
- FABP7 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100737955; called by muse, mutect2, varscan2
- FAT3 | c.1648T>A p.S550T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99966236; called by muse, mutect2, varscan2
- FES | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV99184682; called by muse, mutect2, varscan2
- FMO5 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99566849; called by muse, mutect2, varscan2
- FUNDC2 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 23/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101045532; called by muse, mutect2
- GABRB3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs756312674, COSV59476146; called by muse, mutect2, varscan2
- GLI2 | c.2335G>A p.V779M (on ENST00000361492 / NM_001374353.1; = p.V796M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.703); catalogued as COSV100083212; called by muse, mutect2, varscan2
- GRIK5 | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555872788, COSV53474359; called by muse, mutect2, varscan2
- KCNJ4 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV100341213; called by muse, mutect2
- KRT71 | c.86C>A p.S29* | Nonsense Mutation (SNP) | VAF 6/132 reads (5%) | catalogued as COSV99922157; called by muse, mutect2
- LAMP5 | c.529G>A p.G177R | Missense Mutation (SNP) | VAF 108/131 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747195497, COSV99855582; called by muse, mutect2, varscan2
- LRP2 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); catalogued as rs754884501, COSV99788509; called by muse, mutect2, varscan2
- MAP4K1 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 40/83 reads (48%) | catalogued as rs745506984, COSV67711110, COSV67711312; called by muse, mutect2, varscan2
- MGAM | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101516427; called by muse, mutect2
- MUC5B | c.6278C>T p.S2093F | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV101500338; called by muse, varscan2
- MUC5B | c.9059C>T p.P3020L | Missense Mutation (SNP) | VAF 119/190 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs775518882, COSV101500342; called by muse, mutect2, varscan2
- MUC5B | c.9238C>T p.L3080F | Missense Mutation (SNP) | VAF 115/191 reads (60%) | SIFT tolerated (0.79); PolyPhen benign (0.193); catalogued as rs769759898, COSV101500343; called by muse, mutect2, varscan2
- NLRP8 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs759351908, COSV52585627; called by muse, mutect2, varscan2
- OR2V2 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs528232543, COSV60315154; called by muse, mutect2, varscan2
- OR5AK2 | c.221C>G p.T74S | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as rs375461189, COSV100476032; called by muse, mutect2, varscan2
- OSGEPL1 | c.106C>G p.H36D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.236); catalogued as COSV51464067; called by muse, mutect2
- PCSK2 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs924654760, COSV52741143; called by muse, mutect2, varscan2
- PDE6B | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs757918699, CM1312848, COSV99727555; called by muse, mutect2, varscan2
- PGC | c.662G>C p.S221T | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV100729686; called by muse, mutect2, varscan2
- PMEL | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100657013; called by muse, mutect2, varscan2
- PRDM9 | c.938C>G p.A313G | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV99690369, COSV99690464; called by muse, mutect2, varscan2
- PREX1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV64255885; called by muse, mutect2
- PWWP3B | c.1299G>T p.K433N | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.156); catalogued as COSV100531275, COSV61798530; called by muse, mutect2, varscan2
- RAB17 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs371995454; called by muse, mutect2, varscan2
- RCN1 | c.913A>T p.I305L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV99277263; called by muse, mutect2, varscan2
- RPL9 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.539); catalogued as COSV99787691; called by muse, mutect2, varscan2
- SAG | c.314C>A p.T105K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV101300670; called by muse, mutect2, varscan2
- SCAF11 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV101014366; called by muse, mutect2, varscan2
- SCN2A | c.3445G>T p.G1149* | Nonsense Mutation (SNP) | VAF 37/54 reads (69%) | catalogued as rs1553588962, COSV51842400, COSV99331717; called by muse, mutect2, varscan2
- SIGLEC8 | c.861C>G p.S287R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100367256; called by muse, mutect2, varscan2
- SLC27A5 | c.1544C>A p.S515* | Nonsense Mutation (SNP) | VAF 7/124 reads (6%) | catalogued as rs1380685690, COSV99564369; called by muse, mutect2
- SLC47A1 | c.368T>A p.L123Q | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99565327; called by muse, mutect2, varscan2
- SLC8A3 | c.517A>G p.S173G | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100776201; called by muse, mutect2, varscan2
- STK17B | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.716); catalogued as COSV99826108, COSV99826332; called by muse, mutect2
- SYCP2 | c.1948C>T p.L650F | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100698258; called by muse, mutect2
- TEX45 | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV100861808; called by muse, mutect2
- TF | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1435007880, COSV53919239; called by muse, mutect2, varscan2
- TFAP2D | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV99145927; called by muse, mutect2, varscan2
- TMEM38B | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101020035; called by muse, mutect2, varscan2
- TRDN | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.978); catalogued as COSV100521997; called by muse, mutect2, varscan2
- UCK1 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100944113, COSV64735581; called by muse, mutect2, varscan2
- UNC13B | c.4244G>T p.G1415V | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100266688; called by muse, mutect2, varscan2
- UPP2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs372476628; called by muse, mutect2, varscan2
- UTP25 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101504745; called by muse, mutect2, varscan2
- ARAP3 | c.3621del p.V1208Sfs*79 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by pindel, varscan2
- FOXD4L4 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TP53 | c.389_396del p.L130Hfs*16 | Frame Shift Del (DEL) | VAF 20/34 reads (59%) | called by mutect2, varscan2
- ABCB5 | c.1320G>A p.P440= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs548564211, COSV99328395; called by muse, mutect2, varscan2
- ADH7 | c.417C>A p.T139= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1005770016, COSV99265260; called by muse, mutect2, varscan2
- ASIC2 | c.396C>T p.S132= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs374323534, COSV63296831, COSV63305805; called by muse, mutect2, varscan2
- ATG10 | c.636G>A p.T212= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs560742941, COSV99966867; called by muse, mutect2, varscan2
- CAMSAP3 | c.1581G>A p.S527= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as COSV50330699; called by muse, mutect2, varscan2
- CYP11B1 | c.735T>A p.S245= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99455127; called by muse, mutect2
- DCLRE1C | c.1530C>T p.S510= (on ENST00000378278 / NM_001350965.2; = p.S395= on NM_022487.4) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100543099; called by muse, mutect2, varscan2
- DDX25 | c.672G>T p.G224= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs781263013, COSV99699923; called by muse, mutect2, varscan2
- EHMT1 | c.2742G>A p.A914= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs751905570, COSV101509664; called by muse, mutect2, varscan2
- EP300 | c.123C>T p.H41= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs751573749, COSV54339514; called by muse, mutect2, varscan2
- FLT3LG | c.675C>A p.P225= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV99201310; called by muse, mutect2, varscan2
- MUC5B | c.6324C>T p.T2108= | Silent (SNP) | VAF 115/254 reads (45%) | catalogued as COSV101500339; called by muse, varscan2
- MUC5B | c.12288C>T p.T4096= | Silent (SNP) | VAF 34/193 reads (18%) | called by muse, mutect2, varscan2
- MUC5B | c.12474C>T p.I4158= | Silent (SNP) | VAF 22/222 reads (10%) | called by mutect2, varscan2
- OCA2 | c.1131C>A p.T377= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100667894; called by mutect2, varscan2
- PCDHB3 | c.1665C>T p.N555= | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as rs782769516, COSV99165215; called by muse, mutect2, varscan2
- PCF11 | c.2331C>T p.S777= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs761831604, COSV100018406; called by muse, mutect2, varscan2
- PRKAA1 | c.1062G>A p.A354= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs745466699, COSV57182949; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1917C>A p.A639= (on ENST00000352766; = p.A560= on NM_181334.5) | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100424269; called by muse, mutect2, varscan2
- SPRR3 | c.243T>A p.G81= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs17851565, COSV54878373; called by muse, varscan2
- TRPC7 | c.651G>A p.S217= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs376839341; called by muse, mutect2, varscan2
- TUBB4A | c.894C>T p.N298= | Silent (SNP) | VAF 64/171 reads (37%) | catalogued as COSV99899997; called by muse, mutect2, varscan2
- OFCC1 | n.275T>C | RNA (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- SSPOP | n.9603T>A | RNA (SNP) | VAF 36/132 reads (27%) | catalogued as COSV100947420; called by muse, mutect2, varscan2
- SSPOP | n.14084T>A | RNA (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100947421; called by muse, mutect2, varscan2
